Somatic mutation profile of tumor specimen TCGA-CV-5977-01A (aliquot TCGA-CV-5977-01A-11D-1683-08) from TCGA case TCGA-CV-5977, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,115 days).
Specimen TCGA-CV-5977-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3576bd61-9f1a-45ca-8b6c-b3fe7c409b75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5977-11A (Solid Tissue Normal), aliquot TCGA-CV-5977-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae3ec4fb-9289-4f62-9240-88a9800de4e6

The open-access MAF lists 97 somatic variants for this specimen: 66 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 29, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 2, 5'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 14/16 reads (88%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993G>A p.Q331= | Splice Region (SNP) | VAF 19/65 reads (29%) | catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TTN | c.3034C>T p.R1012* (on ENST00000591111; = p.R966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs397517547, CM1410919, COSV59870865; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD3 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1272799973, COSV64642280; called by muse, mutect2, varscan2
- ACKR1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV63671595; called by muse, mutect2, varscan2
- ACTC1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV51757298; called by muse, mutect2, varscan2
- ADCY8 | c.2116C>G p.Q706E | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV53895249; called by muse, mutect2, varscan2
- ADGRE5 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV99663280; called by muse, mutect2, varscan2
- ALG1 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs774489344, COSV52156206; called by muse, mutect2, varscan2
- AP5Z1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs772283887, COSV100804239; ClinVar: uncertain significance; called by muse, varscan2
- ATN1 | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV63110196, COSV63112331; called by muse, mutect2, varscan2
- CAMSAP1 | c.2442G>C p.M814I | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56718099; called by muse, mutect2, varscan2
- CDH16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs755236039, COSV55334631; called by muse, mutect2, varscan2
- CHST6 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as CM053804, CM065072, COSV60001469; called by muse, mutect2, varscan2
- COL16A1 | c.4644G>A p.M1548I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV54700733; called by muse, mutect2, varscan2
- CUBN | c.6773G>A p.R2258H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.586); catalogued as rs768591141, COSV64707190; called by muse, mutect2, varscan2
- CYP2C19 | c.861G>T p.L287F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64906679; called by muse, mutect2, varscan2
- CYP3A4 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199908125, COSV60500893; called by muse, mutect2, varscan2
- EFCAB6 | c.2573A>G p.E858G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53057630; called by muse, mutect2, varscan2
- EPHA8 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51262367; called by muse, varscan2
- FAT4 | c.3408G>C p.R1136S | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as COSV67880879; called by muse, mutect2, varscan2
- FGFR2 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60639047; called by muse, mutect2, varscan2
- FLNA | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61036707; called by muse, mutect2
- G6PC3 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV52241913; called by muse, mutect2, varscan2
- GRM4 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1430746534, COSV65210203; called by muse, mutect2, varscan2
- GSN | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs777625727, COSV57994369; called by muse, mutect2, varscan2
- GUF1 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV55781341; called by muse, mutect2, varscan2
- HCRTR2 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63793541; called by muse, mutect2, varscan2
- IL3 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs200006770, COSV57309942; called by muse, mutect2, varscan2
- JPT2 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50188479; called by muse, mutect2, varscan2
- KLK3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV58098611; called by muse, mutect2, varscan2
- LAMA1 | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV67531531; called by muse, mutect2, varscan2
- MISP | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138693251; called by muse, mutect2, varscan2
- NLGN2 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57208823; called by muse, mutect2, varscan2
- PCDH15 | c.5000C>A p.P1667H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); catalogued as COSV57259342; called by muse, mutect2, varscan2
- PCDHB8 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50753618; called by muse, mutect2, varscan2
- PCDHGA6 | c.1963T>G p.S655A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99547214; called by muse, mutect2, varscan2
- PCDHGA7 | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1345751127, COSV53901827; called by muse, mutect2, varscan2
- PCLO | c.10589C>T p.P3530L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV61614241, COSV61624784; called by muse, mutect2, varscan2
- PER2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368200140; called by muse, mutect2, varscan2
- PTN | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.303); catalogued as COSV61963101, COSV61968591; called by muse, varscan2
- REXO5 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99759504; called by muse, mutect2
- RHOBTB1 | c.1847G>A p.C616Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61957651; called by muse, mutect2, varscan2
- RNASE12 | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60087241; called by muse, mutect2, varscan2
- RNF168 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58836598; called by muse, mutect2, varscan2
- SCRT2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99857280; called by muse, mutect2, varscan2
- SDF4 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV55417537; called by muse, mutect2
- SEZ6 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253569; called by muse, varscan2
- SFMBT2 | c.2648G>C p.R883T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62804810; called by muse, mutect2, varscan2
- SLC25A39 | c.847C>T p.R283C (on ENST00000377095 / NM_001143780.3; = p.R275C on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1021550910, COSV56586295; called by muse, mutect2, varscan2
- SLITRK1 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs1041104860, COSV65674040, COSV65675357; called by muse, mutect2, varscan2
- SMYD5 | c.207C>T p.A69= | Splice Region (SNP) | VAF 21/50 reads (42%) | catalogued as COSV50264346; called by muse, mutect2, varscan2
- SPATA31D1 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.92); catalogued as rs367962212, COSV61199548; called by muse, mutect2, varscan2
- SUCLA2 | c.927C>G p.I309M (on ENST00000643023; = p.I288M on NM_003850.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1481208397, COSV66221801; called by muse, mutect2, varscan2
- TMEM131L | c.3733G>C p.E1245Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV53640586; called by muse, mutect2, varscan2
- USP53 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV56792103; called by muse, mutect2, varscan2
- ZC3H13 | c.3271G>A p.G1091S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as COSV99668939; called by muse, mutect2, varscan2
- ZNF488 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs149252316; called by muse, mutect2, varscan2
- ZNF534 | c.929C>A p.P310H (on ENST00000332323 / NM_001143939.3; = p.P297H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56513762; called by muse, mutect2
- ZNF708 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV63606813; called by muse, mutect2, varscan2
- ZNF883 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV71308943; called by muse, mutect2, varscan2
- ABL2 | c.2770_2779del p.P924Tfs*13 (on ENST00000502732 / NM_007314.4; = p.P909Tfs*13 on NM_005158.5) | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.748_771del p.M250_E257del | In Frame Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel
- OR4C11 | c.698del p.K233Rfs*10 | Frame Shift Del (DEL) | VAF 43/64 reads (67%) | called by mutect2, pindel, varscan2
- TRGV2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ACTL9 | c.1230C>T p.I410= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs1555753224, COSV61004527; called by muse, mutect2, varscan2
- ADAMTS13 | c.2211C>T p.C737= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs587731476, COSV63019863; called by muse, mutect2, varscan2
- ADGRF5 | c.1086G>A p.K362= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV51929518; called by mutect2, varscan2
- ATG10 | c.579G>C p.L193= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV56422253; called by mutect2, varscan2
- CELF2 | c.558G>A p.Q186= (on ENST00000416382 / NM_001025077.3; = p.Q193= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59969017, COSV59970162; called by muse, mutect2, varscan2
- COL1A2 | c.3171T>C p.G1057= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as CD090283, COSV51952528; called by muse, mutect2, varscan2
- CPT1A | c.603G>A p.R201= | Silent (SNP) | VAF 98/247 reads (40%) | catalogued as COSV55752593; called by muse, mutect2, varscan2
- CYP11A1 | c.1533C>T p.F511= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV51430517; called by muse, mutect2, varscan2
- DCHS1 | c.5904T>C p.R1968= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV55029957; called by muse, mutect2, varscan2
- ERICH3 | c.1464C>T p.D488= | Silent (SNP) | VAF 74/129 reads (57%) | catalogued as rs772724576, COSV58598544, COSV58619346; called by muse, mutect2, varscan2
- FBXL18 | c.948G>A p.P316= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs762477603, COSV66665011; called by muse, mutect2, varscan2
- GRIN2A | c.372C>T p.I124= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV58018850, COSV58025687; called by muse, mutect2, varscan2
- GRM6 | c.1221G>A p.A407= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs544297690, COSV51432864, COSV99179554; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1368G>A p.V456= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as rs782349649, COSV100736468; called by muse, mutect2, varscan2
- GYS2 | c.1815C>T p.Y605= | Silent (SNP) | VAF 52/162 reads (32%) | catalogued as rs931924071, COSV53920292; called by muse, mutect2, varscan2
- ITIH1 | c.1452T>C p.D484= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV56251828; called by muse, mutect2, varscan2
- LRRC8D | c.288C>T p.N96= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as rs367601002; called by muse, mutect2, varscan2
- MTUS1 | c.1821C>A p.A607= | Silent (SNP) | VAF 121/156 reads (78%) | catalogued as COSV50550554, COSV50554803; called by muse, mutect2, varscan2
- NEB | c.2931C>T p.D977= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV50806616; called by muse, mutect2, varscan2
- NLRP3 | c.2433C>T p.F811= | Silent (SNP) | VAF 63/97 reads (65%) | catalogued as rs143175395; ClinVar: benign; called by muse, mutect2, varscan2
- TG | c.5598C>A p.V1866= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV55064288; called by muse, mutect2, varscan2
- TTC14 | c.531G>A p.G177= | Silent (SNP) | VAF 76/143 reads (53%) | catalogued as COSV56009203, COSV99931751; called by muse, mutect2, varscan2
- TTN | c.4611C>A p.G1537= (on ENST00000591111; = p.G1491= on NM_003319.4) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV59870835; called by muse, mutect2, varscan2
- WDR54 | c.274C>A p.R92= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV51961119, COSV51962358; called by muse, mutect2, varscan2
- WWC1 | c.3336C>T p.D1112= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs778099412, COSV54645357; called by muse, mutect2, varscan2
- XPNPEP2 | c.1095C>G p.L365= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV64368402; called by muse, mutect2, varscan2
- XXYLT1 | c.612C>T p.I204= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV59980706; called by muse, mutect2, varscan2
- ZNF653 | c.777C>A p.T259= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs914256817, COSV53402037; called by muse, mutect2, varscan2
- ZNF687 | c.1758G>A p.K586= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV55014749; called by muse, mutect2, varscan2
- MIR412 | n.46T>C | RNA (SNP) | VAF 65/142 reads (46%) | called by muse, mutect2, varscan2
- ZNF33A | c.-50A>T | 5'UTR (SNP) | VAF 7/41 reads (17%) | catalogued as rs1244576002, COSV100276220; called by muse, mutect2, varscan2
